Somatic mutation profile of tumor specimen C3L-01142-01 (aliquot CPT0218330007) from CPTAC case C3L-01142, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 42.4 years (15,483 days).
Specimen C3L-01142-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5a69cba-8eb2-436a-8e37-849a8dd3d154.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01142-31 (Blood Derived Normal), aliquot CPT0220250002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39141991-36b7-468d-8dba-63c0d1f39c3c

The open-access MAF lists 55 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 10, Nonsense Mutation 3, 5'Flank 2, Intron 2, Frame Shift Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALAS2 | c.1520C>A p.P507Q | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as HD040025; called by muse, mutect2
- AMY2A | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs777496434, COSV70214489; called by muse, mutect2
- CDC34 | c.188A>C p.K63T | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs761984062; called by muse, mutect2
- CDCA8 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs776371441; called by muse, mutect2, varscan2
- CNTNAP4 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs374909736, COSV56681989, COSV56698811; called by muse, mutect2, varscan2
- COL24A1 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.109); catalogued as rs377469635; called by muse, mutect2, varscan2
- CSMD1 | c.2456C>T p.P819L (on ENST00000520002; = p.P818L on NM_033225.6) | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1342982807; called by muse, mutect2
- MAGEB5 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs1194249073; called by muse, mutect2, varscan2
- MTARC1 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as rs149527832; called by muse, mutect2, varscan2
- MUC16 | c.36914G>A p.R12305H | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs373720975, COSV67441804, COSV67490888; called by muse, mutect2, varscan2
- MXRA5 | c.6391G>A p.A2131T | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1281863285, COSV54234036; called by muse, mutect2, varscan2
- MYOF | c.2225C>T p.S742L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as rs768988755, COSV63703091; called by muse, mutect2
- NOTCH1 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 42/488 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs892114222; called by muse, mutect2
- NT5C1B | c.323G>A p.R108Q (on ENST00000359846 / NM_001199086.2; = p.R48Q on NM_033253.4) | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs142174343, COSV100410115; called by muse, mutect2
- PHKB | c.2830C>T p.R944* | Nonsense Mutation (SNP) | VAF 40/436 reads (9%) | catalogued as rs1176631078, COSV100067617; called by muse, mutect2
- PRKAG3 | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 47/476 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761641320, COSV52103379; called by muse, mutect2, varscan2
- PRPF40B | c.1471C>T p.R491C (on ENST00000380281; = p.R485C on NM_012272.3) | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756035810, COSV56057538; called by muse, mutect2
- RAG1 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1156316128, CM148326, COSV55024808; called by muse, mutect2, varscan2
- RUNX1 | c.1186C>T p.R396C (on ENST00000344691 / NM_001001890.3; = p.R423C on NM_001754.5) | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99038624; called by muse, mutect2, varscan2
- RYR3 | c.5446G>A p.D1816N | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs765473326, COSV66802903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3RF2 | c.1987G>A p.G663R | Missense Mutation (SNP) | VAF 40/399 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs142456711; called by muse, mutect2
- SLC8A3 | c.2338G>A p.G780S (on ENST00000381269 / NM_183002.3; = p.G778S on NM_033262.4) | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778799527; called by muse, mutect2, varscan2
- TIMD4 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 52/542 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.146); catalogued as rs778307540; called by muse, mutect2
- TRMT9B | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs560075298; called by muse, mutect2, varscan2
- ABCA5 | c.3896A>G p.Y1299C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- AMBRA1 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- BCOR | c.2927G>T p.R976L | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BCOR | c.1330T>C p.S444P | Missense Mutation (SNP) | VAF 82/707 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CORO1B | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- DST | c.4312G>T p.E1438* (on ENST00000361203 / NM_001374722.1; = p.E1112* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- FCRL4 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- FRMPD3 | c.1486A>T p.M496L | Missense Mutation (SNP) | VAF 36/363 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.181); called by muse, mutect2
- GRHL3 | c.797C>T p.P266L (on ENST00000350501 / NM_198174.3; = p.P271L on NM_021180.3) | Missense Mutation (SNP) | VAF 44/374 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- KLHL6 | c.136A>T p.K46* | Nonsense Mutation (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- METTL23 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, varscan2
- RALGAPA2 | c.2120A>C p.E707A | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.729); called by muse, mutect2
- RNF14 | c.1117del p.R373Dfs*11 | Frame Shift Del (DEL) | VAF 24/193 reads (12%) | called by mutect2, pindel, varscan2
- RNF168 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.084); called by muse, mutect2
- TRIM71 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- AC006059.2 | c.1983C>T p.S661= | Silent (SNP) | VAF 32/318 reads (10%) | catalogued as rs143303059, COSV59606542; called by muse, mutect2, varscan2
- ATAD3C | c.1128G>A p.E376= | Silent (SNP) | VAF 28/340 reads (8%) | catalogued as COSV58023408; called by muse, mutect2
- ATP8A2 | c.2556C>T p.Y852= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs374883147; called by mutect2, varscan2
- CCDC171 | c.549G>A p.A183= | Silent (SNP) | VAF 15/169 reads (9%) | catalogued as rs149972101; called by muse, mutect2
- ELL3 | c.141G>A p.P47= | Silent (SNP) | VAF 62/449 reads (14%) | called by muse, mutect2, varscan2
- OR6B1 | c.474G>A p.A158= | Silent (SNP) | VAF 31/315 reads (10%) | catalogued as rs562215999, COSV68770285; called by muse, mutect2
- OSM | c.333C>T p.A111= | Silent (SNP) | VAF 41/344 reads (12%) | catalogued as rs373680590, COSV99304220; called by muse, mutect2, varscan2
- PLEKHN1 | c.687G>A p.T229= (on ENST00000379409; = p.T189= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as rs763642681; called by muse, mutect2
- SHROOM3 | c.3663G>A p.S1221= | Silent (SNP) | VAF 41/407 reads (10%) | catalogued as rs1352254698; called by muse, mutect2, varscan2
- SMC1A | c.2637C>A p.A879= | Silent (SNP) | VAF 20/246 reads (8%) | called by muse, mutect2
- ANKRD10 | c.455+5434G>A | Intron (SNP) | VAF 15/136 reads (11%) | catalogued as COSV57443739; called by muse, mutect2, varscan2
- CFL2 | chr14:34714777 C>T | 5'Flank (SNP) | VAF 32/330 reads (10%) | catalogued as rs1335978674; called by muse, mutect2
- DPY19L2P1 | n.3352A>G | RNA (SNP) | VAF 16/176 reads (9%) | catalogued as rs759218245; called by muse, mutect2
- HELB | c.2156-16T>C | Intron (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- SLC48A1 | chr12:47770893 C>T | 5'Flank (SNP) | VAF 20/264 reads (8%) | catalogued as rs377505138, COSV71285300; called by muse, mutect2
- VAPB | c.*1080C>G | 3'UTR (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
